Somatic mutation profile of tumor specimen ALCH-AEO4-TTP1-A (aliquot ALCH-AEO4-TTP1-A-1-0-D-A636-36) from ALCHEMIST case ALCH-AEO4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.3 years (23,843 days).
Specimen ALCH-AEO4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51da821c-3e9e-4d32-80fe-ed29245c4240.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEO4-NB1-A (Blood Derived Normal), aliquot ALCH-AEO4-NB1-A-1-0-D-A635-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94450082-f0d8-4459-909e-4e631c9d5aa1

The open-access MAF lists 76 somatic variants for this specimen: 53 protein-altering or splice-affecting, 12 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 12, Intron 4, Splice Site 3, Frame Shift Del 3, 5'UTR 2, Nonsense Mutation 2, RNA 2, 3'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 143/649 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.97-1G>T p.X33_splice | Splice Site (SNP) | VAF 59/158 reads (37%) | hotspot (GDC flag); catalogued as CS971912, COSV52665806, COSV52762622, COSV52838014; called by muse, mutect2, varscan2
- AP1B1 | c.2794G>A p.A932T | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs765237420; called by muse, mutect2, varscan2
- BAZ2A | c.4924C>T p.R1642C | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1195556344, COSV51638456; called by muse, mutect2, varscan2
- CABIN1 | c.4441A>T p.K1481* | Nonsense Mutation (SNP) | VAF 42/179 reads (23%) | catalogued as rs574052766; called by muse, mutect2, varscan2
- CDH10 | c.1157G>T p.R386M | Missense Mutation (SNP) | VAF 78/448 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV52583250; called by muse, mutect2, varscan2
- CHST5 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60337063; called by muse, mutect2, varscan2
- FANCI | c.3460C>T p.P1154S (on ENST00000310775 / NM_001376911.1; = p.P1094S on NM_018193.3) | Missense Mutation (SNP) | VAF 30/457 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100168582; called by muse, mutect2
- FGF13 | c.69del p.G24Afs*18 | Frame Shift Del (DEL) | VAF 28/195 reads (14%) | catalogued as rs1275888012; called by mutect2, pindel, varscan2
- ISL1 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 28/536 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs759969078, COSV57932855, COSV57932880; called by muse, mutect2
- LAMB2 | c.2882C>T p.T961M | Missense Mutation (SNP) | VAF 49/439 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs764009381, COSV59737466; called by muse, mutect2, varscan2
- MYH10 | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV52599374; called by muse, mutect2, varscan2
- NEO1 | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 45/300 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56070798; called by muse, mutect2, varscan2
- NOX5 | c.2250G>C p.K750N | Missense Mutation (SNP) | VAF 38/384 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV52989193; called by muse, mutect2
- TET1 | c.2617G>A p.V873I | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs199844508, COSV65382410; called by muse, varscan2
- TTC13 | c.515A>G p.E172G | Missense Mutation (SNP) | VAF 19/499 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV64169653; called by muse, mutect2
- UTRN | c.6879G>T p.L2293F | Missense Mutation (SNP) | VAF 14/275 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62337499; called by muse, mutect2
- ADCY2 | c.2532G>C p.E844D | Missense Mutation (SNP) | VAF 57/365 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ADGRB3 | c.3828del p.E1276Dfs*14 | Frame Shift Del (DEL) | VAF 61/341 reads (18%) | called by mutect2, pindel, varscan2
- AEBP1 | c.810G>C p.W270C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- ALMS1 | c.8530C>G p.L2844V | Missense Mutation (SNP) | VAF 36/538 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.412); called by muse, mutect2
- C1orf216 | c.413G>A p.G138D | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CD163L1 | c.3907C>A p.Q1303K | Missense Mutation (SNP) | VAF 124/582 reads (21%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- CDKN2AIPNL | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CPLANE1 | c.8606C>A p.T2869K | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- CPS1 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 76/475 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CRYBG1 | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.099); called by muse, mutect2
- FHOD3 | c.1169C>A p.P390H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- FN1 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 52/645 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- GPR152 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.831); called by muse, varscan2
- GTPBP1 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- IGSF8 | c.241A>G p.T81A | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ISL1 | c.271T>C p.F91L | Missense Mutation (SNP) | VAF 72/362 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KATNAL1 | c.1417T>A p.S473T | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- KCNH5 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 82/468 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.011); called by muse, varscan2
- MARCHF10 | c.2326A>T p.R776W | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCM8 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYL6 | c.52del p.L18Cfs*18 | Frame Shift Del (DEL) | VAF 44/187 reads (24%) | called by mutect2, pindel, varscan2
- NEFM | c.1096C>A p.L366M | Missense Mutation (SNP) | VAF 9/238 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PDZRN3 | c.1399G>T p.G467* | Nonsense Mutation (SNP) | VAF 54/322 reads (17%) | called by muse, mutect2, varscan2
- PKN3 | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PLEKHF2 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 72/354 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- PRPF40A | c.2759C>G p.S920C | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RCAN1 | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- SLC17A6 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SLC4A10 | c.859-2A>G p.X287_splice | Splice Site (SNP) | VAF 43/328 reads (13%) | called by muse, mutect2, varscan2
- STRADA | c.212T>A p.L71Q (on ENST00000336174 / NM_001363786.1; = p.L34Q on NM_153335.6) | Missense Mutation (SNP) | VAF 33/380 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2
- TMEM200A | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UTRN | c.6880A>G p.K2294E | Missense Mutation (SNP) | VAF 12/269 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- VSIG10 | c.1567+1G>C p.X523_splice | Splice Site (SNP) | VAF 26/93 reads (28%) | called by muse, mutect2
- VWF | c.2248G>T p.D750Y | Missense Mutation (SNP) | VAF 84/380 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ZNF239 | c.331A>T p.S111C | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- ZNF585B | c.2050C>A p.H684N | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ACVR1 | c.1003C>A p.R335= | Silent (SNP) | VAF 14/323 reads (4%) | called by muse, mutect2
- CABIN1 | c.4440G>A p.G1480= | Silent (SNP) | VAF 42/182 reads (23%) | called by muse, mutect2, varscan2
- CHD5 | c.3150C>T p.T1050= | Silent (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- NCAPD3 | c.1314C>T p.F438= | Silent (SNP) | VAF 77/398 reads (19%) | called by muse, mutect2, varscan2
- NOTCH4 | c.2832C>T p.T944= | Silent (SNP) | VAF 54/269 reads (20%) | catalogued as COSV66683029; called by muse, mutect2, varscan2
- OLFML2A | c.1845G>T p.P615= | Silent (SNP) | VAF 43/177 reads (24%) | catalogued as COSV56582707; called by muse, mutect2, varscan2
- PSMC2 | c.642C>G p.L214= | Silent (SNP) | VAF 16/356 reads (4%) | catalogued as rs1045617774; called by muse, mutect2
- SORCS3 | c.1578G>A p.L526= | Silent (SNP) | VAF 33/262 reads (13%) | catalogued as rs370747917; called by muse, mutect2, varscan2
- TENM2 | c.6834C>T p.F2278= (on ENST00000518659 / NM_001122679.2; = p.F2039= on NM_001080428.3) | Silent (SNP) | VAF 28/265 reads (11%) | catalogued as rs532202368, COSV69135456; called by muse, mutect2
- TG | c.5577G>A p.V1859= | Silent (SNP) | VAF 25/718 reads (3%) | called by muse, mutect2
- TNR | c.678C>T p.S226= | Silent (SNP) | VAF 38/164 reads (23%) | catalogued as rs1428315249, COSV54916903, COSV99689874; called by muse, mutect2, varscan2
- TTC4 | c.1149G>T p.V383= | Silent (SNP) | VAF 20/320 reads (6%) | called by muse, mutect2
- APOL3 | c.223+3684G>A | Intron (SNP) | VAF 12/270 reads (4%) | called by muse, mutect2
- C4orf50 | c.-882C>T | 5'UTR (SNP) | VAF 65/179 reads (36%) | called by muse, varscan2
- DEFB121 | n.213G>A | RNA (SNP) | VAF 16/336 reads (5%) | catalogued as rs1393368087; called by muse, mutect2
- GP6 | c.*502C>T | 3'UTR (SNP) | VAF 38/554 reads (7%) | catalogued as rs778801507, COSV59977773; called by muse, mutect2
- KLC3 | c.489+64C>T | Intron (SNP) | VAF 4/15 reads (27%) | catalogued as rs113906887; called by muse, varscan2
- MAZ | c.*823A>G | 3'UTR (SNP) | VAF 20/191 reads (10%) | called by muse, mutect2, varscan2
- MIR16-1 | n.40G>C | RNA (SNP) | VAF 11/109 reads (10%) | called by muse, mutect2, varscan2
- MRPS22 | c.729+27T>C | Intron (SNP) | VAF 62/440 reads (14%) | catalogued as rs375870334; called by muse, mutect2, varscan2
- MSH6 | c.-34C>T | 5'UTR (SNP) | VAF 43/134 reads (32%) | catalogued as rs771435695; ClinVar: likely benign; called by muse, mutect2, varscan2
- RERE | c.1203+209_1203+229del | Intron (DEL) | VAF 9/104 reads (9%) | called by mutect2, pindel
- RNA5-8SP2 | chr16:34159717 C>T | 5'Flank (SNP) | VAF 17/75 reads (23%) | catalogued as rs115490511; called by muse, mutect2, varscan2
